Surgical pathology report (de-identified scan), TCGA case TCGA-NH-A50U, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Candler, specimen TCGA-NH-A50U-01A (Primary Tumor).

[page 1 of 3]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

PATIENT: [REDACTED]

ACCT #: [REDACTED]

LOC: [REDACTED]

REG DR: [REDACTED]

AGE/SX: [REDACTED]

ROOM: [REDACTED]

DOB: [REDACTED]

BED: [REDACTED]

STATUS: [REDACTED]

SPEC #: [REDACTED]

RECD: [REDACTED]

STATUS: [REDACTED]

COLL: [REDACTED]

TIME IN FORMALIN: 5:27

hrs.

CLINICAL INFORMATION:

Pre-Op Diagnosis: Colon CA

Remarks:

Specimen(s): A. Liver biopsy
B. Right colon

MICROSCOPIC DIAGNOSIS

A. CORE BIOPSY, LIVER:

- METASTATIC ADENOCARCINOMA FROM COLON PRIMARY

B. COLON, RIGHT, RIGHT HEMICOLECTOMY:

- INVASIVE LOW-GRADE ADENOCARCINOMA WITH MUCINOUS DIFFERENTIATION ARISING IN ASSOCIATION WITH TUBULOVILLOUS ADENOMA OF CECUM
- TUMOR MEASURES 9 CM IN GREATEST DIMENSION AND INVOLVES VISCERAL PERITONEUM
- 17 REGIONAL LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA
- NO ANGIOLYMPHATIC INVASION IDENTIFIED
- PERINEURAL INVASION PRESENT
- MARGINS NEGATIVE WITH CLOSEST MARGIN MESENTERIC/RADIAL WHICH MEASURES 5 MM
- ADDITIONAL FINDINGS:
- SEPARATE SESSILE SERRATED ADENOMA
- APPENDIX WITH PERIAPPENDICEAL CHRONIC INFLAMMATION

1CD-0-3
adenocarcinoma, mucinous, NOS
8480/3
Site: colon, cecum C18.0
w/ 11/7/12

COMMENT(S)

The large mass involving the cecum is an invasive adenocarcinoma with areas of mucinous differentiation noted. While most of the tumor is low grade, there are microscopic foci where the tumor is of a higher histologic grade. The tumor extends into the proximal appendix as well as involves the subserosa of the distal ileum. The patient's carcinoma will be further evaluated for KRAS mutation and mismatch repair defect (by IHC). Additional reports will follow.

CAP PROTOCOL FOR THE EXAMINATION OF SPECIMENS FOR PATIENTS WITH PRIMARY CARCINOMA OF THE COLON AND RECTUM

Based on AJCC/UICC TNM, 7th Edition

SPECIMEN:

Terminal ileum, cecum, appendix, ascending colon, liver biopsy

PROCEDURE:

Right hemicolectomy
Liver biopsy

** CONTINUED ON NEXT PAGE **

[page 2 of 3]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 2

SPEC #: PATIENT: (Continued)

COMMENT(S)

(Continued)

TUMOR SITE: Cecum
TUMOR SIZE: Greatest dimension: 9 cm
MACROSCOPIC TUMOR PERFORATION: Present
HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: Low-grade
MICROSCOPIC TUMOR EXTENSION: Tumor penetrates to the surface of the visceral peritoneum (serosa)
MARGINS: Margins uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 5 mm, mesenteric/radial
TREATMENT EFFECT: No prior treatment
LYMPH-VASCULAR INVASION: Not identified
PERINEURAL INVASION: Present
TUMOR DEPOSITS: Not identified
PATHOLOGIC STAGING: Primary tumor: pT4a
Regional lymph nodes: pN0
Number of lymph nodes examined: 17
Number of lymph nodes involved: 0
Distant metastasis: pM1a

GROSS DESCRIPTION:

A. Received fresh for frozen section, labeled with the patient's name and "liver biopsy" are several core biopsies of pale, tan and red tissue which range from 0.2 to 1 cm in diameter to 0.1 cm each, submitted in block A for frozen section evaluation.

B. Received fresh for tissue banking labeled with the patient's name and "right colon" is a 15 cm segment of large bowel. The bowel includes cecum and a 7.5 cm appendix consistent with a right colon. There is a 13 cm segment of distal ileum. The bowel has a palpable, 9.0 x 7.0 x 5.0 cm mass associated with the cecum. The distal ileum is focally adhered to the mass. The bowel is opened to have an edematous mucosa. There is a focal area of identifiable fungating tumor at the appendiceal os. Visible tumor is 1.5 cm and is deep within the cecum. The tumor comes to within 11.0 cm of the distal margin and is approximately 1.5 cm from the ileocecal valve. There is a sessile 0.3 cm polyp within the ascending colon. The polyp is 7.5 cm from the distal margin. Sectioning of the tumor shows it to bulge beneath the small bowel. The tumor focally involves the wall of the small bowel and possibly to the mucosa. The tumor tracks up the base of the appendix, and there is a large, fetid 3.0 cm abscess cavity in the adipose adjacent to the mass and cecum. The tumor appears to involve the cecal serosa. The radial mesenteric fat margin averages 1.0 cm. The adipose in the region of the cecum and ileocecal valve have centrally necrotic, tumor-replaced, matted lymph nodes. Representative sections are sampled as labeled:

- B1 - proximal margin
- B2 - distal margin
- B3 - sections of appendix to include tip
- B4 - ileocecal valve
- B5, B6 - sections of mesenteric fat margin
- B7 - sections of possible polypoid lesions adjacent to ileocecal valve and

** CONTINUED ON NEXT PAGE **

[page 3 of 3]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

PAGE 3

SPEC #: [REDACTED] PATIENT: [REDACTED] (Continued)

GROSS DESCRIPTION: (Continued)

small bowel
B8 - sessile ascending colon polyp
B9-B11 - tumor pushing from outside beneath small bowel
B12,B13 - tumor extending into base of appendix from cecum to include abscess cavity
B14,B15 - tumor and cecum
B16 - tumor beneath ileocecal valve adjacent to cecum
B17 - tumor extending to cecal serosa
B18-B20 - sections of cecal adipose with tumor
B21,B22 - lymph nodes distal to tumor
B23 - lymph nodes proximal to tumor and mesenteric small bowel fat

A section of tumor is sampled for tissue banking.

INTRAOPERATIVE CONSULTATION:

A. FROZEN SECTION DIAGNOSIS, LIVER BIOPSY:

- METASTATIC ADENOCARCINOMA CONSISTENT WITH COLORECTAL PRIMARY
- RESULTS GIVEN TO DR. [REDACTED] THE OPERATING ROOM AT

B. RIGHT COLON:

- TISSUE PROCESSED FOR TISSUE BANK WITH PORTION OF TUMOR PROVIDED TO TISSUE BANK COORDINATOR

PHOTO DOCUMENTATION

Image Picture Copy Error
Image Picture Copy Error

Signed ____ (signature on file) ____ [REDACTED]

** END OF REPORT **

Source: NCI Genomic Data Commons file f7fbfc46-38b9-4e31-a9dd-d2249aa51d2b (TCGA-NH-A50U.ECEF5C94-4177-48A5-BB03-AA57BA9058A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).